CCDI case PBCBCH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other and ill-defined digestive organs.
https://portal.gdc.cancer.gov/cases/a37f3375-c590-4e77-9890-a720df594822

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Diagnosis record without a diagnosis name: ICD-O-3 morphology code: 8240/3; Tissue or organ of origin: Head of pancreas; Age at diagnosis: 17.2 years (6,295 days).

Biospecimens (3 samples)
- Sample 0DPCXO: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DPCXV, 0DPCY1 (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
